Gene-level copy-number profile of tumor specimen TCGA-IW-A3M5-01A from TCGA case TCGA-IW-A3M5, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 76.3 years (27,869 days).
Specimen TCGA-IW-A3M5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.8e3731a9-16af-446f-9657-2390839f3986.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IW-A3M5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b03c78fb-5836-412f-87a1-eb5276d6b196

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 12; copy number 2: 19,604; copy number 3: 22,001; copy number 4: 14,965; copy number 5: 1,752; copy number 6: 735; copy number 7: 334; copy number 8: 319; copy number 11: 9; copy number 12: 39; copy number 14: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IW-A3M5-01A-22D-A21P-01): tumor purity 0.86, ploidy 3.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,208,082–141,208,376, 1 gene: RPS16P3.
- chr9:21,321,300–22,455,740, 36 genes: IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 710 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:99,545,419–103,403,712, 63 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr2:108,534,355–110,716,595, 61 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr2:110,967,834–112,622,167, 47 genes, copy number 7: RPL5P9, MIR4435-2HG, ACOXL-AS1, BCL2L11, AC108463.2, AC108463.1, AC108463.3, AC068491.1, AC068491.2, RPS14P4, MIR4435-2, PAFAH1B1P2, AC017002.3, AC017002.2, SOCAR, DBF4P2, AC017002.1, ANAPC1, RPL34P8, AC093166.1, CENPNP2, MIR4771-2, AC093166.2, EEF1E1P1, MERTK, RN7SL297P, RTRAFP1, SLC30A6P1, AC093675.1, TMEM87B, AC093675.2, FBLN7, AC092645.1, ZC3H8, AC092645.2, ZC3H6, NDUFB4P6, AC115115.1, RGPD8, VINAC1P, TTL, POLR1B, Y_RNA, CHCHD5, AC012442.2, AC012442.1, AC079922.1.
- chr3:168,249,522–181,836,880, 207 genes, copy number 8–14 (within-gene range 6–14) (broad region; genes not listed).
- chr6:124,644,434–126,258,355, 16 genes, copy number 7: RNF217-AS1, RNF217, TPD52L1, HDDC2, AL121938.1, AL450332.1, AL365259.1, LINC02523, HEY2, NCOA7, NCOA7-AS1, RN7SKP56, HINT3, RNA5SP216, TRMT11, PPP1R14BP5.
- chr12:22,699,859–23,188,807, 1 gene, copy number 8 (within-gene range 3–8): AC084816.1.
- chr12:23,108,458–27,161,393, 68 genes, copy number 8 (broad region; genes not listed).
- chr19:32,824,142–36,916,291, 207 genes, copy number 7 (broad region; genes not listed).
- chr20:34,122,470–34,698,790, 22 genes, copy number 7: RPS2P1, AL031668.2, ASIP, XPOTP1, AL035458.2, AL035458.1, AHCY, AL356299.2, AL356299.1, ITCH, Y_RNA, CDC42P1, ITCH-AS1, ITCH-IT1, MIR644A, FDX1P1, AL109923.1, DYNLRB1, Y_RNA, MAP1LC3A, PIGU, AL118520.1.
- chr20:34,704,339–34,713,439, 1 gene, copy number 7: TP53INP2.
- chr20:43,423,196–43,895,468, 17 genes, copy number 7: EIF4EBP2P1, Y_RNA, SRSF6, AL031681.2, RNU6-1251P, L3MBTL1, Z98752.2, Z98752.3, Z98752.1, SGK2, Z98752.4, IFT52, RPL27AP, MYBL2, GTSF1L, RNU6-639P, LINC01728.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
